Somatic mutation profile of tumor specimen TCGA-BF-A3DN-01A (aliquot TCGA-BF-A3DN-01A-11D-A20D-08) from TCGA case TCGA-BF-A3DN, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 81.6 years (29,801 days).
Specimen TCGA-BF-A3DN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc768178-70cd-416e-9d1c-e34875475d74.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-A3DN-10A (Blood Derived Normal), aliquot TCGA-BF-A3DN-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55515bec-e049-4dfc-9f6c-00ab6199fc9a

The open-access MAF lists 96 somatic variants for this specimen: 65 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 28, Splice Site 3, Nonsense Mutation 2, 3'Flank 1, 5'Flank 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- MAP2K1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 26/90 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1057519732, COSV61068297; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.2332G>A p.E778K | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.322); catalogued as rs779170683, COSV51399738; called by muse, mutect2
- BPIFB3 | c.1118G>A p.G373E | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.602); catalogued as COSV64957123; called by muse, mutect2, varscan2
- CALCR | c.52-2A>G p.X18_splice | Splice Site (SNP) | VAF 68/147 reads (46%) | catalogued as COSV64006168; called by muse, mutect2, varscan2
- CCKBR | c.268A>T p.N90Y | Missense Mutation (SNP) | VAF 60/206 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58099134; called by muse, mutect2, varscan2
- CDH10 | c.727G>A p.G243S | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV52571844; called by muse, varscan2
- CDK12 | c.2644C>T p.R882W | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70999496; called by muse, mutect2, varscan2
- CLCA2 | c.2116G>A p.G706R | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT tolerated (0.84); PolyPhen benign (0.012); catalogued as COSV65286296; called by muse, mutect2, varscan2
- COL7A1 | c.4022G>A p.G1341E | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60391934; called by muse, mutect2, varscan2
- CORIN | c.1590-2A>G p.X530_splice | Splice Site (SNP) | VAF 5/24 reads (21%) | catalogued as COSV56687308; called by muse, mutect2, varscan2
- DNAH9 | c.12496G>A p.D4166N | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.273); catalogued as rs148626653; called by muse, mutect2, varscan2
- DSG4 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 62/118 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768691954, COSV57388964; called by muse, mutect2, varscan2
- EDNRA | c.922G>A p.V308I | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs754487764, COSV60095960; called by muse, mutect2, varscan2
- EML5 | c.4654G>A p.G1552R (on ENST00000380664; = p.G1560R on NM_183387.3) | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61342471; called by muse, mutect2, varscan2
- FAM135B | c.3176C>T p.S1059F | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV52708816; called by muse, mutect2, varscan2
- FBXO31 | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV61147867; called by muse, mutect2, varscan2
- FBXW8 | c.1103C>T p.S368F (on ENST00000309909; = p.S406F on NM_012174.1) | Missense Mutation (SNP) | VAF 49/62 reads (79%) | SIFT tolerated (0.36); PolyPhen benign (0.038); catalogued as rs751418793, COSV59296991; called by muse, mutect2, varscan2
- FLG2 | c.1351C>T p.Q451* | Nonsense Mutation (SNP) | VAF 120/233 reads (52%) | catalogued as COSV66166972; called by muse, mutect2, varscan2
- GABRA5 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 70/139 reads (50%) | SIFT tolerated (0.77); PolyPhen benign (0.199); catalogued as COSV59476339; called by muse, mutect2, varscan2
- GFRAL | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.936); catalogued as rs1562053089, COSV61229102; called by muse, mutect2, varscan2
- HR | c.1671C>G p.H557Q | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV57190952; called by muse, mutect2, varscan2
- IGKV2-30 | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs754108594; called by muse, mutect2, varscan2
- KCNA1 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 48/65 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66836687; called by muse, mutect2
- KCNQ1 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767472291, COSV50101199, COSV50102720; called by muse, mutect2, varscan2
- KIR3DL1 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 156/277 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.413); catalogued as COSV58488414; called by muse, mutect2, varscan2
- KIR3DL3 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 150/269 reads (56%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs756228014, COSV52545674; called by muse, mutect2, varscan2
- KNG1 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 48/80 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53976349; called by muse, mutect2, varscan2
- LMAN2 | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.923); catalogued as COSV57423827; called by muse, mutect2, varscan2
- LSG1 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 56/259 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs970060761, COSV54568747; called by muse, mutect2, varscan2
- LY6H | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV61370373; called by muse, mutect2
- MMP12 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.03); catalogued as COSV58259211; called by muse, mutect2
- MUC16 | c.13549G>A p.E4517K | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.059); catalogued as COSV67449040; called by muse, mutect2, varscan2
- MYH8 | c.2054G>A p.G685E | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV67960793; called by muse, mutect2, varscan2
- MYOM2 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 157/213 reads (74%) | SIFT tolerated (0.27); PolyPhen benign (0.086); catalogued as COSV50703452; called by muse, mutect2, varscan2
- MYT1L | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.337); catalogued as COSV67710494; called by muse, mutect2, varscan2
- NRP1 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 112/178 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1330019086, COSV55161026; called by muse, varscan2
- OSBPL9 | c.1796G>A p.G599E | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61402021; called by muse, mutect2, varscan2
- PAQR8 | c.783C>A p.F261L | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1298502626, COSV62442053; called by muse, mutect2, varscan2
- PCNX3 | c.5351C>T p.S1784L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100856286; called by muse, mutect2, varscan2
- PGLYRP3 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 68/357 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51949162; called by muse, mutect2, varscan2
- PKHD1 | c.11360C>T p.S3787L | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1162568396, COSV64382647; called by muse, mutect2, varscan2
- PLCE1 | c.2414G>A p.R805Q | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs757088793, COSV53335733, COSV99593711; called by muse, mutect2, varscan2
- PTGIR | c.781A>C p.T261P | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.664); catalogued as COSV52191518; called by muse, mutect2, varscan2
- RBSN | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.006); catalogued as COSV53791737; called by muse, mutect2, varscan2
- RECK | c.2462C>T p.P821L | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs748623772, COSV65034760, COSV65036409; called by muse, mutect2, varscan2
- RP1L1 | c.2083G>A p.A695T | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV66752397; called by muse, mutect2, varscan2
- RYR2 | c.2315G>A p.G772E | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63666448; called by muse, mutect2, varscan2
- SLC22A11 | c.1595C>T p.S532L | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0.095); catalogued as COSV57252066; called by muse, mutect2, varscan2
- SNCAIP | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as COSV54403378; called by muse, mutect2, varscan2
- SPEF1 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.46); PolyPhen benign (0.029); catalogued as COSV65728691; called by muse, mutect2, varscan2
- TEAD4 | c.985A>G p.T329A | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV63280179; called by muse, mutect2, varscan2
- TENM1 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 97/159 reads (61%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.091); catalogued as COSV64426169; called by muse, mutect2, varscan2
- TUBB8 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.993); catalogued as COSV59114821; called by muse, varscan2
- UCKL1 | c.1117-1G>A p.X373_splice | Splice Site (SNP) | VAF 41/68 reads (60%) | catalogued as COSV62402390; called by muse, mutect2, varscan2
- UGT1A10 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.258); catalogued as rs145610800; called by muse, mutect2, varscan2
- VCAN | c.2998C>T p.P1000S | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs373991125; called by muse, mutect2, varscan2
- WDR3 | c.2150T>C p.M717T | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs773830110, COSV60453899; called by muse, mutect2, varscan2
- WWC1 | c.1618C>T p.L540F | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs766887306, COSV54646597; called by muse, mutect2, varscan2
- Z83844.2 | c.717G>T p.E239D | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.446); catalogued as COSV60927496; called by muse, mutect2, varscan2
- ZNF221 | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 123/215 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs562929317, COSV52108139; called by muse, mutect2, varscan2
- ZNF382 | c.1024del p.H342Mfs*6 | Frame Shift Del (DEL) | VAF 76/146 reads (52%) | catalogued as COSV53089909; called by mutect2, pindel, varscan2
- ZNF761 | c.1425C>G p.F475L | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV100483347; called by muse, mutect2, varscan2
- ZNF761 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs1215826847, COSV100483348; called by muse, mutect2, varscan2
- ZNF792 | c.1475G>A p.S492N | Missense Mutation (SNP) | VAF 66/98 reads (67%) | SIFT tolerated (0.88); PolyPhen benign (0.36); catalogued as COSV68692813; called by muse, mutect2, varscan2
- ACSS3 | c.405T>C p.S135= | Silent (SNP) | VAF 54/73 reads (74%) | catalogued as COSV54086073; called by muse, mutect2, varscan2
- ARHGEF28 | c.2682C>T p.F894= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV55247467; called by muse, mutect2, varscan2
- BICDL2 | c.747G>A p.R249= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as COSV54155560; called by mutect2, varscan2
- BPIFB3 | c.1119G>A p.G373= | Silent (SNP) | VAF 31/114 reads (27%) | catalogued as COSV100972339; called by muse, mutect2, varscan2
- CHN1 | c.285C>T p.F95= | Silent (SNP) | VAF 22/33 reads (67%) | catalogued as COSV69295160; called by muse, mutect2, varscan2
- DSG3 | c.2247C>T p.F749= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as rs142612259, COSV57124575; called by muse, mutect2, varscan2
- DSG4 | c.2352G>A p.S784= | Silent (SNP) | VAF 58/99 reads (59%) | catalogued as rs1441356137, COSV57388978; called by muse, mutect2, varscan2
- DYNC1H1 | c.6324C>T p.I2108= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as COSV64134805; called by muse, mutect2, varscan2
- IL23R | c.588C>T p.V196= | Silent (SNP) | VAF 46/142 reads (32%) | catalogued as COSV61373078; called by muse, mutect2, varscan2
- KYNU | c.987C>T p.F329= | Silent (SNP) | VAF 171/335 reads (51%) | catalogued as COSV51579794; called by muse, mutect2, varscan2
- LTBP2 | c.4146G>A p.Q1382= | Silent (SNP) | VAF 72/143 reads (50%) | catalogued as COSV56205645; called by muse, mutect2, varscan2
- MEGF8 | c.624G>A p.E208= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs1324727909, COSV52076862; called by muse, mutect2, varscan2
- MME | c.1305G>A p.E435= | Silent (SNP) | VAF 37/172 reads (22%) | catalogued as COSV64706198; called by muse, mutect2, varscan2
- MROH7 | c.3319C>T p.L1107= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs373000422; called by muse, mutect2, varscan2
- NEXMIF | c.1017C>A p.P339= | Silent (SNP) | VAF 41/64 reads (64%) | catalogued as COSV50022642; called by muse, mutect2, varscan2
- NLRC5 | c.1932C>T p.F644= | Silent (SNP) | VAF 84/171 reads (49%) | catalogued as COSV52650132; called by muse, mutect2, varscan2
- OR13H1 | c.186C>T p.F62= | Silent (SNP) | VAF 69/107 reads (64%) | catalogued as COSV58547159; called by muse, mutect2, varscan2
- PCDHA7 | c.1836A>G p.Q612= | Silent (SNP) | VAF 33/157 reads (21%) | catalogued as rs1397719197, COSV65342326; called by muse, mutect2, varscan2
- PCDHB7 | c.1722G>A p.E574= | Silent (SNP) | VAF 89/143 reads (62%) | catalogued as COSV50755600; called by muse, mutect2, varscan2
- PDS5B | c.2205G>A p.A735= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs757484452, COSV59724134; called by muse, mutect2, varscan2
- PLA2G4D | c.1071C>T p.F357= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as COSV51819441; called by muse, mutect2, varscan2
- PTPRT | c.2253C>T p.I751= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs771479479, COSV61963962, COSV62011133; called by muse, mutect2, varscan2
- SH2D3C | c.579G>A p.L193= (on ENST00000314830 / NM_170600.3; = p.L36= on NM_005489.4) | Silent (SNP) | VAF 78/109 reads (72%) | catalogued as COSV59119179; called by muse, mutect2, varscan2
- SLC1A7 | c.933C>T p.I311= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as COSV65198309; called by muse, mutect2, varscan2
- STAMBPL1 | c.1275G>A p.G425= | Silent (SNP) | VAF 63/98 reads (64%) | catalogued as COSV64228794; called by muse, mutect2, varscan2
- TSPAN14 | c.573T>A p.P191= | Silent (SNP) | VAF 23/31 reads (74%) | catalogued as COSV55419858; called by muse, mutect2, varscan2
- TTN | c.34536G>A p.P11512= (on ENST00000591111; = p.P10585= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as rs371945519, COSV60102119; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- ZCCHC2 | c.2901C>T p.G967= | Silent (SNP) | VAF 32/103 reads (31%) | catalogued as COSV54036391; called by muse, mutect2, varscan2
- HMGB1P1 | n.352C>T | RNA (SNP) | VAF 79/144 reads (55%) | called by muse, mutect2, varscan2
- RN7SL106P | chr15:23163913 G>A | 5'Flank (SNP) | VAF 22/91 reads (24%) | called by muse, mutect2, varscan2
- TRNAU1AP | chr1:28581011 A>G | 3'Flank (SNP) | VAF 47/134 reads (35%) | called by muse, mutect2, varscan2
